Somatic mutation profile of tumor specimen TCGA-IG-A625-01A (aliquot TCGA-IG-A625-01A-11D-A31U-09) from TCGA case TCGA-IG-A625, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 60.4 years (22,070 days).
Specimen TCGA-IG-A625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e5e69c7-3edd-46cd-b21e-2b8b87f122d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A625-10A (Blood Derived Normal), aliquot TCGA-IG-A625-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1abb195e-5e6e-40e9-a92b-16fae8aca463

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 1, In Frame Del 1, In Frame Ins 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960047; called by muse, mutect2
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 26/33 reads (79%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- BDH1 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs201898088; called by mutect2, varscan2
- CD200R1 | c.847G>A p.V283I (on ENST00000471858 / NM_170780.3; = p.V306I on NM_138806.4) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.419); catalogued as rs763301923, COSV55601016; called by muse, mutect2, varscan2
- CD5L | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs377627339, COSV63821922; called by muse, mutect2
- GPRIN2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs781801723, COSV65400461; called by muse, mutect2, varscan2
- HS3ST1 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50026550; called by muse, mutect2, varscan2
- KBTBD7 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.604); catalogued as COSV65266847; called by muse, mutect2, varscan2
- MROH2B | c.1255C>A p.H419N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV68186719; called by muse, mutect2, varscan2
- MYO1F | c.3114G>C p.Q1038H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as rs187667984; called by muse, mutect2, varscan2
- NLRP4 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149428225; called by muse, mutect2, varscan2
- REV3L | c.7696A>G p.M2566V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs368840674; called by muse, mutect2, varscan2
- SENP6 | c.1936A>G p.I646V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1562040838, COSV100519635; called by muse, mutect2, varscan2
- SOWAHD | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1474568080; called by muse, mutect2, varscan2
- SPATA16 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV63529622; called by muse, mutect2, varscan2
- TJAP1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs370044590; called by muse, mutect2, varscan2
- ARHGEF17 | c.3920C>T p.S1307F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP1A1 | c.880A>T p.I294F | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- BUB1 | c.2783+2C>A p.X928_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- CARD9 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.018); called by muse, varscan2
- CNTN6 | c.933del p.Q311Hfs*42 | Frame Shift Del (DEL) | VAF 13/24 reads (54%) | called by mutect2, pindel, varscan2
- CRY2 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- DMRTB1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- FAM199X | c.918C>G p.N306K | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GRHL2 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- HTT | c.666_677del p.S223_E226del | In Frame Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- IMMP2L | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM6A | c.3158A>T p.K1053I | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- KITLG | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP8 | c.2690_2691dup p.D898Lfs*59 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- MAP3K2 | c.1121A>T p.Y374F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MCHR1 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.3649G>T p.E1217* | Nonsense Mutation (SNP) | VAF 63/190 reads (33%) | called by muse, mutect2, varscan2
- MYO1B | c.3276G>T p.E1092D (on ENST00000304164; = p.E1034D on NM_012223.5) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NIT2 | c.236A>T p.Y79F | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- PRKDC | c.9179C>T p.S3060F | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PTER | c.1042T>G p.F348V | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- RAB32 | c.283dup p.Y95Lfs*13 | Frame Shift Ins (INS) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- SCN4A | c.3444G>A p.V1148= | Splice Region (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2, varscan2
- STAMBP | c.298T>C p.F100L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TCF7 | c.918_918+1insTCTCGG p.R306_W307insSR | In Frame Ins (INS) | VAF 8/23 reads (35%) | called by mutect2, varscan2
- VN1R1 | c.428A>T p.N143I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- WASHC5 | c.2378A>G p.K793R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZBTB14 | c.432T>G p.Y144* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- CDH10 | c.1776A>G p.Q592= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV52591860; called by muse, mutect2, varscan2
- DCAF12 | c.1056C>A p.I352= | Silent (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- GLB1L3 | c.1812A>G p.G604= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- GOLGB1 | c.8713T>C p.L2905= | Silent (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- IGLV3-12 | c.346C>T p.*116= | Silent (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- ITPA | c.246G>A p.G82= | Silent (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- KLK2 | c.297G>A p.P99= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs759727230; called by muse, varscan2
- RAB3C | c.258A>C p.T86= | Silent (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- TTN | c.3318C>T p.G1106= (on ENST00000591111; = p.G1060= on NM_003319.4) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs141768043; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- VWF | c.2307C>A p.P769= | Silent (SNP) | VAF 19/26 reads (73%) | called by muse, mutect2, varscan2
- ZBTB7A | c.570G>A p.A190= | Silent (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- ZNHIT1 | c.450G>A p.L150= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- MTCL1 | c.2968-3220dup | Intron (INS) | VAF 12/32 reads (38%) | catalogued as rs754891814; called by mutect2, varscan2
